Somatic mutation profile of tumor specimen MP2PRT-PAPZBM-TMP1-A (aliquot MP2PRT-PAPZBM-TMP1-A-1-0-D-A83N-36) from MP2PRT case MP2PRT-PAPZBM, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.0 years (1,080 days).
Specimen MP2PRT-PAPZBM-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1e314ba4-6d4c-491b-9d1a-711c86f086b1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAPZBM-NM1-A (Blood Derived Cancer - Bone Marrow, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAPZBM-NM1-A-1-0-D-A83N-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ce21dfea-153f-41f1-8094-c5479cdd761c

The open-access MAF lists 4 somatic variants for this specimen: 3 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 3, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NBPF3 | c.1451C>T p.P484L | Missense Mutation (SNP) | VAF 10/126 reads (8%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs750177940; called by muse, mutect2
- ADCY2 | c.560T>C p.L187P | Missense Mutation (SNP) | VAF 40/199 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- FAM184B | c.2338G>T p.A780S | Missense Mutation (SNP) | VAF 18/231 reads (8%) | SIFT tolerated (0.63); PolyPhen benign (0.001); called by muse, mutect2
- ZNF268 | c.1131A>C p.S377= | Silent (SNP) | VAF 104/373 reads (28%) | called by muse, mutect2, varscan2
